TCGA case TCGA-CJ-4637 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/772e3aed-f211-42a1-9ab2-1c543f581541

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 52 years; Vital status: Dead; Days to death: 2,227 days (6.1 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 52.3 years (19,101 days); Year of diagnosis: 2004; AJCC pathologic T: T2b; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temsirolimus; Initial disease status: Progressive Disease; Days to treatment start: 47 days; Days to treatment end: 476 days (1.3 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Recombinant Interferon Alfa-2a; Initial disease status: Progressive Disease; Days to treatment start: 51 days; Days to treatment end: 476 days (1.3 years); Route of administration: Subcutaneous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Interferon Alfa-2B; Initial disease status: Progressive Disease; Days to treatment start: 484 days (1.3 years); Days to treatment end: 507 days (1.4 years); Route of administration: Subcutaneous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sunitinib Malate; Initial disease status: Progressive Disease; Days to treatment start: 512 days (1.4 years); Days to treatment end: 816 days (2.2 years); Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Initial disease status: Progressive Disease; Days to treatment start: 849 days (2.3 years); Days to treatment end: 861 days (2.4 years); Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 1,174 days (3.2 years); Days to treatment end: 1,185 days (3.2 years); Treatment dose: 300 cGy; Course number: 2; Number of fractions: 10; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Nanoparticle Albumin-Bound Rapamycin; Initial disease status: Progressive Disease; Days to treatment start: 1,213 days (3.3 years); Days to treatment end: 1,468 days (4.0 years); Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bortezomib; Initial disease status: Progressive Disease; Days to treatment start: 1,476 days (4.0 years); Days to treatment end: 1,742 days (4.8 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 1,755 days (4.8 years); Days to treatment end: 1,770 days (4.8 years); Treatment dose: 360 cGy; Course number: 3; Number of fractions: 3; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 1,787 days (4.9 years); Days to treatment end: 1,787 days (4.9 years); Treatment dose: 240 cGy; Course number: 4; Number of fractions: 1; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,868 days (5.1 years); Days to treatment end: 1,883 days (5.2 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Initial disease status: Progressive Disease; Days to treatment start: 1,868 days (5.1 years); Days to treatment end: 1,888 days (5.2 years); Route of administration: Subcutaneous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 1,903 days (5.2 years); Days to treatment end: 1,918 days (5.3 years); Treatment dose: 3,600 cGy; Course number: 5; Number of fractions: 12; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Pazopanib; Initial disease status: Progressive Disease; Days to treatment start: 1,962 days (5.4 years); Days to treatment end: 2,053 days (5.6 years); Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 2,070 days (5.7 years); Days to treatment end: 2,074 days (5.7 years); Treatment dose: 300 cGy; Course number: 6; Number of fractions: 5; Treatment anatomic sites: Distant Site.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 57.3 years (20,922 days); Days to diagnosis: 1,821 days (5.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 1,821 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 2,227 days (6.1 years); Disease response: With Tumor.
- ECOG performance status: 2; Timepoint: Recurrence/Progression.

Molecular and laboratory tests
- Platelets: Elevated.
- Lactate Dehydrogenase: Normal.
- Calcium: Normal.
- Leukocytes: Normal.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CJ-4637-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-CJ-4637-01A-01-BS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-CJ-4637-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-CJ-4637-01A-02-BS2: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-CJ-4637-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CJ-4637-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.3; Intermediate dimension: 0.9; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: No.
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 4: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: nab-rapamycin; Therapy regimen: Progression.
- Drug treatment 6: Pharmaceutical therapy drug name: AZD; Therapy regimen: Progression.
- Drug treatment 6, Route of administrations: Route of administration: SC.
- Drug treatment 7: Pharmaceutical therapy drug name: Sutent; Therapy regimen: Progression.
- Drug treatment 9: Pharmaceutical therapy drug name: Roferon-A; Therapy regimen: Progression.
- Drug treatment 10: Pharmaceutical therapy drug name: Intron A; Therapy regimen: Progression.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Performance status timing: At Recurrence/Progression Of Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,227 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,227 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,821 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CJ-4637-01A-02D-1322-01): tumor purity 0.31, ploidy 1.96, whole-genome doublings 0.
